Somatic mutation profile of tumor specimen MP2PRT-PAPADT-TBP1-A (aliquot MP2PRT-PAPADT-TBP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PAPADT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (575 days).
Specimen MP2PRT-PAPADT-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01601823-6b91-4530-ad16-f71bac992870.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPADT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPADT-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b0febab-c462-41e1-86fa-5ab843da0b75

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 109/263 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RBM23 | c.532C>T p.R178W (on ENST00000359890 / NM_001077351.2; = p.R162W on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/380 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs774365880, COSV57128716; called by muse, mutect2, varscan2
- TENM3 | c.3769G>A p.V1257I | Missense Mutation (SNP) | VAF 124/432 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.939); catalogued as rs774602911, COSV101304641, COSV69306077; called by muse, mutect2, varscan2
- EGF | c.796A>G p.M266V | Missense Mutation (SNP) | VAF 112/339 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGA5 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 162/356 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ABHD11 | c.876G>A p.P292= | Silent (SNP) | VAF 164/341 reads (48%) | catalogued as rs143792326; called by muse, mutect2, varscan2
- PAPPA2 | c.4893C>A p.I1631= | Silent (SNP) | VAF 82/195 reads (42%) | catalogued as COSV62810035; called by muse, mutect2, varscan2
